Surgical pathology report (de-identified scan), TCGA case TCGA-BW-A5NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-BW-A5NO-01A (Primary Tumor).

[page 1 of 3]
Specimen Inquiry

PAGE 1

ACCT #:
STATUS:
DOB:

Flags: *H *L = Critical H,L = Abnormal #=Delta ** = Alpha Abn * Mic Abn

SURGICAL PROCEDURES:
EXCISION, RESECTION

GROSS DESCRIPTION

A. The specimen is submitted fresh as "right hepatic lobe" and consists of a wedge-shaped apparent hepatic lobe weighing 985 grams and measuring 17 x 14 x 8.5 cm. The capsule is red tan, interrupted by a bulging irregular gray bulging nodular area measuring 8 x 6 cm approaching 1.7 cm of the surgical margin which has been marked with black dye. The capsular area of the nodule has been marked with blue dye. Sectioning reveals the lesion to be gelatinous in areas with a yellow orange coloration. Upon sectioning the lesion approaches to within 0.6 cm of the nearest inked margin. Sectioning reveals two possible satellite nodules measuring 0.7 and 1.5 cm located 2 cm from the primary lesion approaching to within 2 cm of the inked margin.

The gallbladder is also identified adherent to the hepatic tissue measuring 6 x 2.5 x 2.5 cm containing thickened green yellow bile without identified calculi. The gallbladder wall has a uniform thickness of 0.2 cm. The mucosa is yellow to green tan and trabeculated. The cystic duct is not clearly defined. Representative sections are submitted, 14 (14):

Cassettes 1-4:	Tumor capsule
Cassettes 5-6:	Tumor margin of resection
Cassettes 7-8:	Tumor with adjacent uninvolved parenchyma
Cassettes 9-10:	Satellite nodules
Cassettes 11-12:	Tumor with adjacent gallbladder wall
Cassettes 13-14:	Representative sections of uninvolved parenchyma

Note: Gross photographs of the specimen have been taken. Additional tissue has been submitted for TCGA studies.

B. The specimen is submitted in formalin as "abdominal wall excision" and consists of a red tan to gray tan irregular ragged fragment of tissue, unoriented, measuring 5 x 3.5 x 1.2 cm. Serial sectioning is unremarkable. Representative sections are submitted; 2 (2).

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED] Unit [REDACTED]

ICD-0-3
Carcinoma, hepatocellular NOS
8176/3
Site: Liver, hepatic NOS C22.0
JW 2/4/13

[page 2 of 3]
Specimen Inquiry

Patient

ACCT#: [REDACTED]

(Continued)

FINAL DIAGNOSIS

- A. LIVER, RIGHT HEPATIC LOBE, RESECTION:
- HEPATOCELLULAR CARCINOMA, MULTIPLE (LARGEST IS 8 CM; OTHERS ARE 1.5 CM, 0.7 CM, AND 0.2 CM). SEE SYNOPTIC REPORT.
- B. ABDOMINAL WALL, EXCISION:
- FIBROSIS, HEMORRHAGE AND GRANULATION TISSUE ADJACENT SKELETAL MUSCLE.
- NO MALIGNANCY IS NOTED.

SYNOPTIC REPORT

SYNOPTIC REPORT: LIVER (AND INTRAHEPATIC BILE DUCTS)
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: TOTAL RIGHT HEPATIC LOBECTOMY
TUMOR FOCALITY: MULTIPLE
TUMOR SIZE: 8 CM (LARGEST)
HISTOLOGIC TYPE: HEPATOCELLULAR CARCINOMA
HISTOLOGIC GRADE: MODERATELY TO FOCALLY POORLY DIFFERENTIATED (GRADE 2-3 OF 4)

LYMPH-VASCULAR INVASION:

MACROSCOPIC VENOUS (LARGE VESSEL) INVASION (V): NOT IDENTIFIED.
MICROSCOPIC (SMALL VESSEL) INVASION (L): FOCI SUSPICIOUS FOR INVASION.

TUMOR EXTENSION: CONFINED TO LIVER

MARGINS:

f,,, PARENCHYMAL: UNINVOLVED.
f,, DISTANCE TO CLOSEST MARGIN: 1.7 CM FROM RESECTION MARGIN

LYMPH NODES:

f,,, # INVOLVED/ # EXAMINED: N/A

OTHER PERTINENT FINDINGS:

- THREE SATELLITE TUMOR NODULES (1.5 CM, 0.7 CM, 0.2 CM) ARE NOTED AT APPROXIMATELY 2 CM FROM THE DOMINANT TUMOR NODULE (8 CM).
- BACKGROUND LIVER SHOWS CHRONIC HEPATITIS (CLINICAL HISTORY OF HEPATITIS C) WITH MODERATE PORTAL ACTIVITY WITH MILD INTERFACE ACTIVITY, MILD LOBULITIS AND FIBROUS PORTAL EXPANSION WITH FOCAL

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acc: [REDACTED]

Uni: [REDACTED]

[page 3 of 3]
Specimen Inquiry

ACCT# [REDACTED]

(Continued)

SYNOPTIC REPORT

(Continued)

BRIDGING FIBROSIS (ISHAK FIBROSIS SCORE 3 OF 6).

- NO STEATOSIS IS NOTED.
- INCIDENTAL BILE DUCT ADENOMA (0.1 CM)
- TRICHROME STAIN HAS BEEN PERFORMED TO HIGHLIGHT THE FIBROSIS.

pTNM STAGE: pT3a

Signed (Electronically) < SIGNATURE ON FILE >

PATHOLOGIST

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED]

Unit# [REDACTED]

Dis-/Synchroous Primary Note		✓

Source: NCI Genomic Data Commons file 22ac6934-e3bc-4a7b-877f-32869a56d1b6 (TCGA-BW-A5NO.39E090EF-9EA0-4362-BB47-432DE5AA1393.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).